Gene-level copy-number profile of tumor specimen TCGA-FI-A2F8-01A from TCGA case TCGA-FI-A2F8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 64.7 years (23,649 days).
Specimen TCGA-FI-A2F8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.a32fe338-a25a-4702-9e9a-8f95f6b13c74.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FI-A2F8-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5a18f53b-a994-44db-b5ee-73846bef16dc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 10,362; copy number 3: 11,542; copy number 4: 22,066; copy number 5: 8,871; copy number 6: 5,769; copy number 7: 492; copy number 8: 394; copy number 9: 94; copy number 10: 55; copy number 13: 6; copy number 14: 10; copy number 16: 124; copy number 17: 1; copy number 20: 12; copy number 25: 5; copy number 26: 2; copy number 34: 2; copy number 43: 2; copy number 61: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FI-A2F8-01A-12D-A17C-01): tumor purity 0.5, ploidy 3.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 315 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,372,186–234,647,571, 13 genes, copy number 9: AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5.
- chr2:174,072,447–175,905,502, 36 genes, copy number 10 (within-gene range 5–10): OLA1, AC013467.1, RN7SL65P, Y_RNA, LRRC2P1, HNRNPA1P39, LINC01305, AC018470.1, SP9, CIR1, SCRN3, GPR155, AC010894.1, RPA3P1, AC010894.4, AC010894.2, RNU6-5P, WIPF1, AC010894.3, H3P6, CHRNA1, CHN1, RNU6-763P, RNU6-1290P, RPL21P31, ATF2, AC007435.1, MIR933, AC096649.1, ATP5MC3, Y_RNA, RPS15AP14, AC093459.1, EXTL2P1, AC016751.2, AC016751.1.
- chr2:177,623,244–178,108,339, 2 genes, copy number 9 (within-gene range 7–9): PDE11A, PDE11A.
- chr2:177,953,111–182,131,398, 62 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr3:107,834,586–107,928,907, 1 gene, copy number 17 (within-gene range 4–43): LINC00636.
- chr3:108,032,456–108,091,862, 2 genes, copy number 43 (within-gene range 6–43): AC012020.1, CD47.
- chr3:168,858,659–169,038,416, 5 genes, copy number 20: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr3:169,613,510–169,966,734, 19 genes, copy number 10 (within-gene range 5–10): AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3.
- chr5:36,192,589–37,066,413, 14 genes, copy number 9: NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31.
- chr6:131,135,467–131,283,535, 1 gene, copy number 9 (within-gene range 6–9): AKAP7.
- chr6:131,469,059–131,584,332, 2 genes, copy number 9 (within-gene range 6–9): RPL21P67, ARG1.
- chr11:57,861,948–60,744,212, 124 genes, copy number 16 (broad region; genes not listed).
- chr11:63,838,928–63,988,346, 7 genes, copy number 20 (within-gene range 4–20): MARK2, RNU6-1306P, RCOR2, NAA40, RNU6-45P, COX8A, AP000721.1.
- chr12:71,439,798–71,667,725, 6 genes, copy number 26–61 (within-gene range 4–61): LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1.
- chr17:39,671,122–39,747,291, 5 genes, copy number 25 (within-gene range 2–25): PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr20:47,209,214–47,656,877, 10 genes, copy number 14 (within-gene range 6–14): ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1.
- chr20:53,544,615–53,741,797, 6 genes, copy number 13: Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
